Somatic mutation profile of tumor specimen TCGA-XU-A933-01A (aliquot TCGA-XU-A933-01A-11D-A423-09) from TCGA case TCGA-XU-A933, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 52.8 years (19,276 days).
Specimen TCGA-XU-A933-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc4870b5-8142-4bdd-8ea4-6c07e83aeae5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A933-10A (Blood Derived Normal), aliquot TCGA-XU-A933-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d7c0fdb-9ecb-4f80-8ec3-ae4da7b037bf

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Frame Shift Del 4, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC244197.3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113993946, CM128959, CM930422, CM950672, CX149681; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRD7 | c.1365T>G p.Y455* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | hotspot (GDC flag); catalogued as COSV67158199, COSV67158513; called by muse, mutect2, varscan2
- KIT | c.1676T>G p.V559G | Missense Mutation (SNP) | VAF 24/74 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913517, CM013551, COSV55386973, COSV55388782, COSV55393324; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs1344615174, COSV51939552; called by muse, mutect2, varscan2
- APLF | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104411187; called by muse, mutect2, varscan2
- ARMCX2 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs1236877965, COSV57529313, COSV57531289; called by muse, mutect2, varscan2
- CARD14 | c.2983A>G p.K995E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs760244588; called by muse, mutect2, varscan2
- CASS4 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs770674921; called by muse, mutect2
- HECW2 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs763718773; called by muse, mutect2, varscan2
- MCMDC2 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs200037793; called by muse, mutect2, varscan2
- MUC16 | c.38062C>A p.L12688I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs761436091, COSV67479744; called by muse, mutect2, varscan2
- POP1 | c.2500G>A p.G834S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs751972489; called by muse, mutect2, varscan2
- RGS1 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1231909201; called by muse, mutect2, varscan2
- SPEG | c.2908G>A p.V970M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs377353278; called by muse, mutect2, varscan2
- CARD17 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASS4 | c.1860A>T p.E620D | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.063); called by muse, mutect2
- CHD8 | c.4741del p.V1581Yfs*7 (on ENST00000646647 / NM_001170629.2; = p.V1302Yfs*7 on NM_020920.4) | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- CTNND2 | c.842_857del p.Q281Pfs*46 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- FBXO28 | c.846_879del p.S283Nfs*11 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- FOXN1 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- MID1 | c.1388T>C p.V463A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIIP | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.122); called by mutect2, varscan2
- ODC1 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- QRICH2 | c.4660del p.R1554Gfs*35 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- SLC18B1 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ADGRV1 | c.12168G>C p.V4056= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- ATP10A | c.975A>C p.A325= | Silent (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- DNAH17 | c.9558G>A p.A3186= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs376694280, COSV67749151; called by muse, mutect2, varscan2
- FRG2C | c.75A>G p.Q25= | Silent (SNP) | VAF 17/281 reads (6%) | called by muse, mutect2
- HEATR5A | c.5469T>C p.D1823= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1566744220; called by muse, mutect2, varscan2
- MYBL2 | c.1107C>T p.T369= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs181688716; called by muse, mutect2, varscan2
- OR2W3 | c.567C>T p.C189= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs773034036, COSV64457487; called by muse, mutect2, varscan2
- TTN | c.30015C>T p.D10005= (on ENST00000591111; = p.D9078= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs587780979, COSV59862495; ClinVar: benign; called by muse, mutect2, varscan2
- UBAP2L | c.2493A>C p.P831= | Silent (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- FXYD6P3 | n.246C>T | RNA (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
